Gene-level copy-number profile of tumor specimen ALCH-B067-TTP1-A from ALCHEMIST case ALCH-B067, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.1 years (24,522 days).
Specimen ALCH-B067-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b44ad96d-e702-420e-9a73-8a4a6564d0d1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B067-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,744 have no estimate.
https://portal.gdc.cancer.gov/files/3dfce54f-f762-46d2-99d6-0463416c38b8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 110; copy number 1: 9,832; copy number 2: 48,579; copy number 3: 347; copy number 4: 5; copy number 5: 5; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:62,189,131–62,211,666, 3 genes (within-gene range 0–1): PIGPP2, RPS15AP7, Y_RNA.
- chr2:91,686,102–91,714,745, 1 gene: AC027612.2.
- chr3:47,346,950–47,349,073, 1 gene: AC104447.1.
- chr5:80,288,449–80,332,541, 6 genes: KRT18P45, AC026410.1, AC026410.4, AC026410.2, SPZ1, RBMX2P5.
- chr6:39,299,001–39,322,968, 2 genes: KCNK17, KCNK16.
- chr8:22,165,140–22,212,326, 3 genes (within-gene range 0–1): BMP1, AC105206.1, AC105206.3.
- chr8:41,840,059–41,840,339, 1 gene (within-gene range 0–1): RN7SL149P.
- chr17:74,417,594–74,417,704, 1 gene: RNA5SP448.
- chr20:56,700,837–56,701,514, 1 gene: PTMAP6.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:194,402,672–194,498,364, 2 genes, copy number 5 (within-gene range 2–5): ATP13A3, AC108676.2.
- chr7:69,594,793–69,597,493, 1 gene, copy number 5: CT66.
- chr8:22,106,874–22,109,419, 1 gene, copy number 5: NUDT18.
- chr9:132,582,606–132,590,252, 1 gene, copy number 6: BARHL1.
- chr19:3,762,682–3,768,575, 1 gene, copy number 5: MRPL54.

Autosomal genes at a single copy (total copy number 1): 7,189. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
